MMRF case MMRF_1506 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7e683316-3409-49ec-af3e-474d21edbeb5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.6 years (19,954 days); ISS stage: III; Days to last known disease status: 1,226 days (3.4 years); Days to last follow up: 1,226 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 105 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 8.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 68.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 1.47 g/L; Immunoglobulin A 104 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 5.67 µg/mL; Lactate Dehydrogenase 1.38 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 23 g/L; Total Protein 14.5 g/dL; Glucose 6.11 mmol/L.
- Day 102 (ECOG 0): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 2.13 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 6.38 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 10.9 mmol/L.
- Day 295 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.42 mg/dL; Immunoglobulin G 3.21 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.39 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.67 mmol/L.
- Day 365: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.036 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 4.39 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.6 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 561: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.18 mmol/L.
- Day 688: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 1,226 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 0.97 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day 1: Weight: 63 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1506_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1506_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
